Somatic mutation profile of tumor specimen C3L-07535-03 (aliquot CPT0477300006) from CPTAC case C3L-07535, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.3 years (27,130 days).
Specimen C3L-07535-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05e8e42a-2572-4105-81a0-9fcd80415a4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07535-31 (Blood Derived Normal), aliquot CPT0475590006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d65666ac-55a7-4ce2-840c-9766cb8b171a

The open-access MAF lists 2,674 somatic variants for this specimen: 1,986 protein-altering or splice-affecting, 594 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,429, Silent 594, Frame Shift Del 391, Frame Shift Ins 66, Nonsense Mutation 65, Intron 57, 3'UTR 13, Splice Region 12, In Frame Del 11, 5'UTR 9, Splice Site 9, 5'Flank 7.

Variants (750 of 2,674; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.2420G>A p.C807Y | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1064793480, CM931185; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARG1 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 27/344 reads (8%) | catalogued as rs104893944, CM993111; ClinVar: pathogenic; called by muse, mutect2
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 58/462 reads (13%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by pindel, varscan2
- CCND3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 77/617 reads (12%) | hotspot (GDC flag); catalogued as COSV57828583; called by muse, mutect2, varscan2
- COL5A1 | c.3752del p.P1251Rfs*25 | Frame Shift Del (DEL) | VAF 57/386 reads (15%) | catalogued as rs786205100; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CYP17A1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 56/461 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894149, CM024701, COSV64005060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DOK7 | c.1263del p.S422Hfs*34 | Frame Shift Del (DEL) | VAF 78/672 reads (12%) | catalogued as rs606231129; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 26/231 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, varscan2
- HLCS | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119103229, CM960833, COSV100358162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.4168dup p.A1390Gfs*42 | Frame Shift Ins (INS) | VAF 45/446 reads (10%) | catalogued as rs756471180; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRPPRC | c.2966G>A p.R989H | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs774857058, COSV53236937; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 44/271 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1057519733, CM083720, COSV61068654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.482del p.P161Rfs*10 | Frame Shift Del (DEL) | VAF 75/608 reads (12%) | catalogued as rs763195944; ClinVar: pathogenic; called by pindel, varscan2
- MOCS2 | c.65del p.P22Hfs*2 | Frame Shift Del (DEL) | VAF 48/394 reads (12%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 67/253 reads (26%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NEB | c.18886C>T p.R6296* | Nonsense Mutation (SNP) | VAF 35/386 reads (9%) | catalogued as rs763364977, CM1413926; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NEK1 | c.1908del p.V637Cfs*34 | Frame Shift Del (DEL) | VAF 26/239 reads (11%) | catalogued as rs775849720; ClinVar: likely pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 34/240 reads (14%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PDZD7 | c.166dup p.R56Pfs*24 | Frame Shift Ins (INS) | VAF 50/465 reads (11%) | catalogued as rs587776894; ClinVar: pathogenic / risk factor; called by mutect2, varscan2
- RDH12 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs28940314, CM042103, CM118725, COSV99961791; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AARS1 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 53/427 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866956348; ClinVar: uncertain significance; called by muse, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 29/206 reads (14%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel, varscan2
- ABCA3 | c.3107C>T p.T1036M | Missense Mutation (SNP) | VAF 78/588 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs769945799, COSV57057286; called by muse, mutect2, varscan2
- ABCC8 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 47/497 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs758462294; called by muse, mutect2
- ABHD14A-ACY1 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT deleterious, low confidence (0); catalogued as rs762895482; called by muse, mutect2
- ABR | c.1885C>T p.R629* (on ENST00000302538 / NM_021962.5; = p.R592* on NM_001092.5) | Nonsense Mutation (SNP) | VAF 20/486 reads (4%) | catalogued as rs776303770; called by muse, mutect2
- AC006059.2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs746616993; called by muse, mutect2, varscan2
- AC011455.2 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 51/384 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs780899400; called by muse, mutect2, varscan2
- AC099489.1 | c.4466C>T p.S1489L | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs752098095; called by muse, mutect2, varscan2
- ACAD10 | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 49/447 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV58154509; called by muse, mutect2, varscan2
- ACAD10 | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 51/421 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770585998; called by muse, mutect2, varscan2
- ACKR3 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs750460737; called by muse, mutect2, varscan2
- ACSF3 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as rs559765310, COSV58079107, COSV58082470; called by muse, mutect2, varscan2
- ACTR2 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV53200709, COSV99573982; called by muse, mutect2, varscan2
- ADAM22 | c.1633G>T p.G545* | Nonsense Mutation (SNP) | VAF 42/441 reads (10%) | catalogued as COSV55978013; called by muse, mutect2
- ADAM30 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs148305137, COSV101023880; called by muse, mutect2
- ADAM7 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1392058067; called by muse, mutect2
- ADAM8 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750746913, COSV101291633; called by muse, mutect2, varscan2
- ADAMTS13 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs782630536; called by muse, mutect2, varscan2
- ADAMTS13 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 89/634 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs281875340, CM040366, COSV52469773; ClinVar: not provided; called by muse, mutect2, varscan2
- ADAMTS8 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375607745; called by muse, mutect2, varscan2
- ADCY5 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 68/518 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV71901583; called by muse, mutect2, varscan2
- ADCY6 | c.2824G>A p.A942T | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.645); catalogued as COSV100326596; called by muse, mutect2, varscan2
- ADCY8 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368219344, COSV53913378; called by muse, mutect2, varscan2
- ADD2 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 42/365 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs150426440; called by muse, varscan2
- ADGRA2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 62/642 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs766009635; called by muse, mutect2
- ADGRB2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 74/629 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs373774455; called by muse, mutect2, varscan2
- ADGRE5 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 50/409 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs776974784, COSV54414114, COSV99663161; called by muse, mutect2, varscan2
- ADGRL2 | c.2853del p.K951Nfs*54 (on ENST00000370717 / NM_001366005.1; = p.K938Nfs*54 on NM_012302.4) | Frame Shift Del (DEL) | VAF 45/304 reads (15%) | catalogued as COSV54672325; called by mutect2, varscan2
- ADGRL3 | c.4093G>A p.A1365T (on ENST00000506720 / NM_001322402.2; = p.A1254T on NM_015236.6) | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.182); catalogued as rs749889713, COSV72230669; called by muse, varscan2
- AEN | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 58/588 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1320192454; called by muse, mutect2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 50/464 reads (11%) | catalogued as rs748399150; called by mutect2, varscan2
- AGO4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs773809553, COSV64616987; called by muse, mutect2, varscan2
- AHNAK2 | c.13555G>A p.D4519N | Missense Mutation (SNP) | VAF 45/451 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as rs770925361, COSV60925013; called by muse, mutect2
- AHNAK2 | c.8765A>G p.K2922R | Missense Mutation (SNP) | VAF 86/650 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.924); catalogued as rs372696524; called by muse, mutect2, varscan2
- AIRE | c.1103del p.P368Rfs*10 | Frame Shift Del (DEL) | VAF 43/328 reads (13%) | catalogued as COSV52398550; called by mutect2, pindel, varscan2
- ALDH4A1 | c.768del p.N257Tfs*77 | Frame Shift Del (DEL) | VAF 66/507 reads (13%) | catalogued as COSV51894665; called by mutect2, pindel, varscan2
- ALG12 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 67/710 reads (9%) | PolyPhen benign (0.006); catalogued as rs367671008; ClinVar: uncertain significance; called by muse, mutect2
- ALPI | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 64/476 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1445528675, COSV55013473; called by muse, mutect2, varscan2
- ANKAR | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs145081425; called by muse, mutect2, varscan2
- ANKRD18B | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.152); catalogued as rs760567222; called by muse, mutect2, varscan2
- ANKRD24 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 99/752 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as rs985849731; called by muse, mutect2, varscan2
- ANKRD27 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 31/362 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs756043262, COSV100043176; called by muse, mutect2
- ANKRD28 | c.3089A>G p.N1030S | Missense Mutation (SNP) | VAF 46/359 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs770795796; called by muse, mutect2, varscan2
- ANKRD31 | c.4263dup p.Q1422Tfs*12 | Frame Shift Ins (INS) | VAF 64/356 reads (18%) | catalogued as rs530301594; called by mutect2, varscan2
- ANKRD6 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 58/505 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs530838661; called by muse, mutect2, varscan2
- ANO4 | c.926G>A p.R309Q (on ENST00000392977 / NM_001286615.2; = p.R274Q on NM_178826.4) | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs757024624, COSV100152812, COSV100153324; called by muse, mutect2, varscan2
- ANTKMT | c.657del p.G220Dfs*19 | Frame Shift Del (DEL) | VAF 70/688 reads (10%) | catalogued as rs766564345; called by mutect2, pindel
- ANXA8 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 58/1064 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1220680586; called by muse, mutect2
- AOC3 | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 43/415 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs201143286, COSV53825736; called by muse, mutect2, varscan2
- APBA2 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs753422882, COSV67104774; called by muse, mutect2
- APOB | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769425660, COSV51938544; called by muse, mutect2, varscan2
- AQP12A | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 82/632 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs771981901; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 38/321 reads (12%) | catalogued as rs774148781; called by mutect2, varscan2
- ARFGEF1 | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs1442160635; called by muse, mutect2
- ARHGEF10 | c.3392C>T p.T1131M (on ENST00000398564; = p.T1106M on NM_014629.4) | Missense Mutation (SNP) | VAF 80/848 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs367794138; called by muse, mutect2
- ARHGEF26 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV62845345; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 69/482 reads (14%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARMC5 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 84/531 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1352073481, COSV51655445; called by muse, mutect2, varscan2
- ASCC2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143452344, COSV100316549; called by muse, mutect2, varscan2
- ASMTL | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 41/828 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101187650; called by muse, mutect2
- ATAD5 | c.693del p.D232Mfs*21 | Frame Shift Del (DEL) | VAF 44/477 reads (9%) | catalogued as COSV58972719; called by mutect2, pindel
- ATF4 | c.406del p.Q136Rfs*3 | Frame Shift Del (DEL) | VAF 58/488 reads (12%) | catalogued as rs770192882; called by mutect2, pindel, varscan2
- ATF6B | c.1992del p.S665Rfs*46 | Frame Shift Del (DEL) | VAF 83/790 reads (11%) | catalogued as rs1562900790; called by mutect2, pindel, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 38/334 reads (11%) | catalogued as rs771531141; called by mutect2, varscan2
- ATN1 | c.3455G>A p.R1152H | Missense Mutation (SNP) | VAF 64/478 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1165161265, COSV57546776; called by muse, mutect2, varscan2
- ATP2B2 | c.38del p.N13Tfs*94 | Frame Shift Del (DEL) | VAF 43/387 reads (11%) | catalogued as COSV59494570; called by mutect2, pindel, varscan2
- ATP6V0D2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 29/319 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.666); catalogued as rs777381409, COSV53414052; called by muse, mutect2
- ATP9A | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs769835554; called by muse, mutect2, varscan2
- AUTS2 | c.3710C>T p.T1237M | Missense Mutation (SNP) | VAF 60/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1012077245, COSV61431113; called by muse, varscan2
- AUTS2 | c.3755C>T p.T1252M | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs149469010; called by muse, varscan2
- AVL9 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 52/390 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs748745500, COSV59465498; called by muse, mutect2, varscan2
- AXIN1 | c.1523del p.G508Vfs*197 | Frame Shift Del (DEL) | VAF 94/700 reads (13%) | catalogued as rs760961378; called by mutect2, pindel, varscan2
- AXL | c.2315C>T p.A772V (on ENST00000301178 / NM_021913.5; = p.A763V on NM_001699.6) | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs748675894; called by muse, mutect2, varscan2
- AZU1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 68/712 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1177339145; called by muse, mutect2
- B3GNT2 | c.924del p.F309Sfs*9 | Frame Shift Del (DEL) | VAF 49/411 reads (12%) | catalogued as rs1300549233; called by mutect2, pindel, varscan2
- B4GALT5 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV65495321; called by muse, mutect2
- BAG6 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 64/498 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs143680960; called by muse, mutect2, varscan2
- BARHL2 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 73/502 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV99059756; called by muse, mutect2, varscan2
- BCAN | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 60/437 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.311); catalogued as rs761137329, COSV100228101; called by muse, mutect2, varscan2
- BCAR1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 82/676 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs568888027; called by muse, mutect2, varscan2
- BLMH | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | catalogued as rs765998771; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 90/361 reads (25%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597116, COSV61757588; called by muse, mutect2, varscan2
- BNC2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 56/442 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1181349194; called by muse, mutect2, varscan2
- BNIP3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs1451737717, COSV64043886; called by muse, mutect2, varscan2
- BOC | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 66/619 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as rs998774925; called by muse, mutect2, varscan2
- BPIFC | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 52/412 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs766182794; called by muse, varscan2
- BRAF | c.836T>C p.M279T | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV99972989; called by muse, mutect2, varscan2
- BRAT1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 59/586 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.115); catalogued as rs780327501, COSV61395053; called by muse, mutect2
- BRD1 | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 46/678 reads (7%) | catalogued as COSV53462357; called by muse, mutect2
- BRD9 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 81/483 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as rs375839207; called by muse, mutect2, varscan2
- BRF2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 62/626 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs751550570, COSV55102689; called by muse, mutect2
- BRIP1 | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs587782427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1454129707; called by muse, mutect2, varscan2
- BSN | c.6194C>T p.S2065L | Missense Mutation (SNP) | VAF 44/608 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs201009128; called by muse, mutect2
- BST1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.626); catalogued as rs971320175; called by muse, varscan2
- BUB3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765842898; called by muse, mutect2, varscan2
- C11orf42 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 63/486 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762717228, COSV56413587; called by muse, mutect2, varscan2
- C1QTNF4 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 67/539 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV56784403; called by muse, mutect2, varscan2
- C20orf203 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750670496; called by muse, mutect2
- C2CD2L | c.869T>G p.L290R | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV60884525; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 55/363 reads (15%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C2orf81 | c.1300C>A p.L434I | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.111); catalogued as COSV104391983; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 37/279 reads (13%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2
- C7orf50 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs199870517; called by muse, mutect2, varscan2
- C8orf74 | c.393G>T p.Q131H | Missense Mutation (SNP) | VAF 77/635 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as rs374889281; called by muse, mutect2, varscan2
- CACNA1C | c.4609C>T p.R1537C | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59704693; called by muse, mutect2
- CACNA1I | c.6641C>T p.P2214L | Missense Mutation (SNP) | VAF 62/610 reads (10%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1410154484; called by muse, mutect2
- CACNA2D2 | c.2375G>A p.R792H (on ENST00000479441 / NM_001174051.3; = p.R785H on NM_006030.4) | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1011668282, COSV56562017; called by muse, mutect2, varscan2
- CALML5 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 90/695 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs999235185, COSV66702730; called by muse, mutect2, varscan2
- CAMK4 | c.848del p.L283Wfs*7 | Frame Shift Del (DEL) | VAF 26/248 reads (10%) | catalogued as COSV100000351; called by mutect2, pindel, varscan2
- CAMSAP3 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50332429; called by muse, varscan2
- CANX | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1329319100, COSV99910578; called by muse, mutect2, varscan2
- CAPN11 | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 35/411 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs769234047, COSV67238872; called by muse, mutect2
- CAPN9 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 41/476 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs753743813, COSV55232827; called by muse, mutect2
- CARS2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1195058620; called by muse, varscan2
- CASK | c.2620C>T p.R874C (on ENST00000378163 / NM_001367721.1; = p.R869C on NM_003688.3) | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1204576497, COSV59364263; called by muse, mutect2
- CATSPER3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs775604213, COSV50948638; called by muse, mutect2, varscan2
- CATSPER4 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100128408; called by muse, mutect2
- CC2D2A | c.3196C>T p.P1066S | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV67502943; called by muse, mutect2, varscan2
- CCDC116 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 63/545 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148804210, COSV53037087; called by muse, mutect2, varscan2
- CCDC120 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 76/626 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs782570114, COSV100900719; called by muse, mutect2, varscan2
- CCDC166 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 82/968 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV72638747; called by muse, mutect2
- CCDC175 | c.1895del p.N632Tfs*8 | Frame Shift Del (DEL) | VAF 29/222 reads (13%) | catalogued as rs1198843594; called by mutect2, varscan2
- CCDC182 | c.64del p.M22* | Frame Shift Del (DEL) | VAF 47/395 reads (12%) | catalogued as rs1567992795; called by mutect2, pindel, varscan2
- CCDC22 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 71/514 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868939480, COSV66050832; called by muse, mutect2, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 27/216 reads (13%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC66 | c.254del p.N85Mfs*3 (on ENST00000394672 / NM_001353147.1; = p.N51Mfs*3 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 51/276 reads (18%) | catalogued as rs751844604; called by mutect2, varscan2
- CCDC66 | c.2173A>C p.K725Q (on ENST00000394672 / NM_001353147.1; = p.K691Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs767100961; called by mutect2, varscan2
- CCDC88C | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 59/509 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770482247; called by muse, mutect2, varscan2
- CCL24 | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 86/357 reads (24%) | catalogued as rs201399079; called by muse, mutect2, varscan2
- CCT4 | c.869T>A p.I290N | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1374484735; called by muse, mutect2, varscan2
- CD109 | c.3035G>A p.R1012K | Missense Mutation (SNP) | VAF 43/394 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV54647769; called by muse, mutect2, varscan2
- CDC40 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1415787702; called by muse, mutect2
- CDC42BPB | c.4469G>A p.R1490H | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1487900395, COSV63476039; called by muse, varscan2
- CDCA7 | c.997C>T p.R333W (on ENST00000347703 / NM_145810.3; = p.R412W on NM_031942.5) | Missense Mutation (SNP) | VAF 43/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142891986; called by muse, mutect2, varscan2
- CDCP2 | c.672del p.T225Pfs*86 | Frame Shift Del (DEL) | VAF 77/561 reads (14%) | catalogued as COSV100313590; called by mutect2, pindel, varscan2
- CDH15 | c.1796del p.G599Afs*80 | Frame Shift Del (DEL) | VAF 71/617 reads (12%) | catalogued as rs749838702; called by mutect2, pindel, varscan2
- CDH22 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 43/427 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868551234, COSV64837083; called by muse, mutect2
- CDH8 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 48/518 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs1466326562; called by muse, mutect2
- CDHR5 | c.1547del p.P516Rfs*253 (on ENST00000358353 / NM_001171968.2; = p.P522Rfs*253 on NM_021924.5) | Frame Shift Del (DEL) | VAF 88/777 reads (11%) | catalogued as rs746645774, COSV57641552; called by mutect2, pindel, varscan2
- CDK16 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 53/479 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as rs1329975919, COSV52091107; called by muse, mutect2, varscan2
- CEBPA | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 72/493 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1216191482; called by mutect2, varscan2
- CEL | c.391G>A p.A131T (on ENST00000673714; = p.A128T on NM_001807.6) | Missense Mutation (SNP) | VAF 31/422 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1269812562; called by muse, mutect2
- CELSR1 | c.6371C>T p.T2124M | Missense Mutation (SNP) | VAF 63/462 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs771037022, COSV53094051; called by muse, mutect2, varscan2
- CENPJ | c.3506G>A p.R1169H | Missense Mutation (SNP) | VAF 35/423 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753604037, COSV55041334; called by muse, mutect2
- CENPJ | c.121_124del p.D41Kfs*27 | Frame Shift Del (DEL) | VAF 51/554 reads (9%) | catalogued as rs775811228; called by mutect2, pindel
- CENPVL3 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 90/692 reads (13%) | SIFT tolerated, low confidence (0.08); catalogued as rs1418318658; called by muse, mutect2, varscan2
- CEP112 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs774572812, COSV101211130; called by muse, mutect2, varscan2
- CEP164 | c.3296T>G p.V1099G | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV99633380; called by muse, mutect2
- CEP164 | c.4081C>T p.R1361C | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs753906680, COSV54047316; called by muse, mutect2, varscan2
- CEP170B | c.1550G>A p.R517Q (on ENST00000453495; = p.R446Q on NM_015005.3) | Missense Mutation (SNP) | VAF 60/726 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.958); catalogued as rs750666951; called by muse, mutect2
- CEP250 | c.4351C>T p.R1451W | Missense Mutation (SNP) | VAF 74/468 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs780139027, COSV61169818; called by muse, mutect2, varscan2
- CEP68 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 65/498 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs1276657961; called by muse, mutect2, varscan2
- CEP83 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs759737051; called by muse, mutect2, varscan2
- CERK | c.1124C>A p.A375E | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV99348640; called by muse, mutect2, varscan2
- CFAP44 | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs763039505, COSV55610571; called by muse, mutect2, varscan2
- CFAP46 | c.3187G>T p.G1063C | Missense Mutation (SNP) | VAF 38/364 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV100886339; called by muse, mutect2, varscan2
- CFAP54 | c.5885G>A p.G1962D | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.125); catalogued as rs1199241795, COSV61572414; called by muse, mutect2, varscan2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 51/394 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CGN | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 58/559 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs779332921; called by muse, mutect2, varscan2
- CHAC1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 73/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs149942687; called by muse, varscan2
- CHCHD2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 57/479 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs200784526, COSV68170030; called by muse, mutect2, varscan2
- CHD4 | c.3245G>A p.R1082H (on ENST00000357008 / NM_001363606.2; = p.R1095H on NM_001273.5) | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1308430527; called by muse, mutect2, varscan2
- CHD7 | c.7145C>T p.T2382M | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs189926848, COSV71107549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD8 | c.3779G>A p.R1260H (on ENST00000646647 / NM_001170629.2; = p.R981H on NM_020920.4) | Missense Mutation (SNP) | VAF 40/465 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101303158; called by muse, mutect2
- CHD8 | c.2827C>T p.R943C (on ENST00000646647 / NM_001170629.2; = p.R664C on NM_020920.4) | Missense Mutation (SNP) | VAF 42/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67871401; called by muse, mutect2, varscan2
- CHD9 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 36/504 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs369288866; called by muse, mutect2
- CHGB | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 58/425 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs759534931, COSV66761604; called by muse, mutect2, varscan2
- CHML | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs911830187, COSV59362859; called by muse, mutect2
- CHMP6 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 56/428 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs777217739, COSV100289460; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 84/374 reads (22%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRM4 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 86/600 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as rs747938778; called by muse, mutect2, varscan2
- CHRM5 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 59/459 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs774588600, COSV67246946; called by muse, mutect2, varscan2
- CHST12 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 76/720 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1408721621; called by muse, mutect2, varscan2
- CHST4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 74/511 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs144089831; called by muse, mutect2, varscan2
- CHST5 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 76/567 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as rs1361958917; called by muse, mutect2, varscan2
- CIC | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 78/563 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs770830842; called by muse, mutect2, varscan2
- CLCN2 | c.1142dup p.G382Wfs*21 | Frame Shift Ins (INS) | VAF 39/323 reads (12%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLEC11A | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 71/542 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs771124798, COSV51574619; called by muse, mutect2, varscan2
- CLIP2 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 171/605 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.048); catalogued as rs782350168; called by muse, mutect2, varscan2
- CLIP2 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs782008375, COSV56282484, COSV56287235; called by muse, mutect2
- CLPTM1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 74/501 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777780659; called by muse, mutect2, varscan2
- CNNM2 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 85/611 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV63995495; called by muse, mutect2, varscan2
- CNP | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 45/382 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs372029848, COSV66367890; called by muse, mutect2, varscan2
- CNRIP1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99721301; called by muse, varscan2
- CNTNAP1 | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs141390466; called by muse, mutect2, varscan2
- CNTNAP2 | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 77/708 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); catalogued as rs1012333307, COSV62154521; called by muse, mutect2, varscan2
- COBL | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 57/511 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1429734083, COSV54337586; called by muse, mutect2, varscan2
- COL18A1 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 75/514 reads (15%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as rs1427629521; called by muse, mutect2, varscan2
- COL1A2 | c.1090-1G>T p.X364_splice | Splice Site (SNP) | VAF 28/337 reads (8%) | catalogued as COSV51956737; called by muse, mutect2
- COL24A1 | c.1580C>A p.P527H | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65304614; called by muse, mutect2
- COL27A1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 51/497 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100621391; called by muse, mutect2, varscan2
- COL6A3 | c.3310C>A p.P1104T | Missense Mutation (SNP) | VAF 51/422 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs749985377; called by muse, varscan2
- COL8A2 | c.281del p.P94Lfs*143 | Frame Shift Del (DEL) | VAF 75/614 reads (12%) | catalogued as rs1277273445; called by mutect2, pindel, varscan2
- COMMD5 | c.303del p.T102Pfs*3 | Frame Shift Del (DEL) | VAF 72/691 reads (10%) | catalogued as rs754887321; called by mutect2, pindel, varscan2
- COPA | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616448; called by muse, mutect2
- COX8C | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs759791285; called by muse, mutect2
- CPSF3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 61/399 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs1449023124, COSV53009379; called by muse, varscan2
- CPT1C | c.1612T>C p.S538P | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs759089399; called by muse, mutect2
- CPVL | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV55308489; called by muse, mutect2, varscan2
- CRACD | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 101/697 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs779771309, COSV99949602; called by muse, mutect2, varscan2
- CRACDL | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 86/676 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs759470403; called by muse, mutect2, varscan2
- CRTAC1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 84/530 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs375692428; called by muse, mutect2, varscan2
- CSMD1 | c.665C>A p.P222Q | Missense Mutation (SNP) | VAF 52/479 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs748546639; called by muse, varscan2
- CSPG4 | c.5983C>T p.R1995W | Missense Mutation (SNP) | VAF 77/575 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs529993656, COSV57902610; called by muse, varscan2
- CTNNA2 | c.2047del p.I683* | Frame Shift Del (DEL) | VAF 43/392 reads (11%) | catalogued as COSV58143187; called by mutect2, pindel, varscan2
- CTU2 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 56/511 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs138922002; called by muse, mutect2, varscan2
- CUBN | c.3833G>A p.C1278Y | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913794; called by muse, mutect2, varscan2
- CUL7 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.551); catalogued as rs768504882; called by muse, mutect2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | catalogued as rs772257590; called by mutect2, varscan2
- CXXC5 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 88/540 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs764721156; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 38/238 reads (16%) | catalogued as rs745836350; called by mutect2, varscan2
- CYBA | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1458945605; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 67/569 reads (12%) | catalogued as rs756254049; called by pindel, varscan2
- CYGB | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 43/503 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs868605420; called by muse, mutect2
- CYLC2 | c.747del p.D250Mfs*106 | Frame Shift Del (DEL) | VAF 60/434 reads (14%) | catalogued as COSV100872458; called by mutect2, pindel, varscan2
- CYP17A1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250463562, CM920226, COSV64004840; called by muse, mutect2, varscan2
- CYP2J2 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs752285305; called by muse, mutect2, varscan2
- CYP4F2 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 52/501 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs762122740, COSV55621925; called by muse, mutect2, varscan2
- CYP4F3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 63/525 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs113330239, COSV55413386; called by muse, mutect2, varscan2
- DAG1 | c.2335C>T p.R779W | Missense Mutation (SNP) | VAF 43/570 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886042574, COSV58186037; ClinVar: uncertain significance; called by muse, mutect2
- DAXX | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 112/829 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs776829106; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 30/190 reads (16%) | catalogued as COSV99245498; called by mutect2, pindel
- DCAF11 | c.780-1G>T p.X260_splice | Splice Site (SNP) | VAF 29/272 reads (11%) | catalogued as COSV58108215; called by muse, mutect2, varscan2
- DCC | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59121986; called by muse, mutect2, varscan2
- DCP1A | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs781860038; called by muse, mutect2
- DCTD | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 46/398 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1297073291, COSV63866669; called by muse, mutect2, varscan2
- DDX21 | c.609C>T p.G203= | Splice Region (SNP) | VAF 37/261 reads (14%) | catalogued as rs1398434321, COSV100826540; called by muse, mutect2, varscan2
- DDX50 | c.1017dup p.Y340Ifs*7 | Frame Shift Ins (INS) | VAF 41/366 reads (11%) | catalogued as rs747282010; called by mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 20/150 reads (13%) | catalogued as rs778036194; called by mutect2, varscan2
- DENND11 | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.738); catalogued as COSV101530728, COSV72097633; called by muse, mutect2, varscan2
- DENND4B | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 84/623 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs765925737; called by muse, mutect2, varscan2
- DEPTOR | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs147092773; called by muse, mutect2, varscan2
- DGKK | c.3698G>A p.R1233H | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs782099622; called by muse, mutect2, varscan2
- DIAPH2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs757562335; called by muse, mutect2, varscan2
- DIDO1 | c.6661G>A p.A2221T | Missense Mutation (SNP) | VAF 70/544 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs201786226, COSV99827256; called by muse, varscan2
- DIPK2A | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 67/597 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs200656208; called by muse, mutect2, varscan2
- DIRAS2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 61/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65369937; called by muse, mutect2, varscan2
- DISP3 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 66/537 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764393813, COSV53820716; called by muse, mutect2, varscan2
- DLEC1 | c.2282A>G p.Y761C | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV57304579; called by muse, mutect2
- DLG4 | c.328C>T p.R110C (on ENST00000399506 / NM_001321075.3; = p.R153C on NM_001365.4) | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57239103; called by muse, mutect2, varscan2
- DLX6 | c.273C>G p.H91Q | Missense Mutation (SNP) | VAF 35/990 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1238166124; called by muse, mutect2
- DMRTB1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 79/495 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs781325131, COSV101008254; called by muse, mutect2, varscan2
- DMRTC2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 53/441 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs375134520, COSV99523288; called by muse, mutect2, varscan2
- DNAH11 | c.8926C>T p.R2976* | Nonsense Mutation (SNP) | VAF 35/321 reads (11%) | catalogued as rs1298378020, COSV60940337; called by muse, mutect2, varscan2
- DNAH2 | c.4979C>T p.T1660M | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770495244; called by muse, mutect2, varscan2
- DNAH3 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 60/391 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs756811397, COSV54529625; called by muse, mutect2, varscan2
- DNAH5 | c.10281G>T p.K3427N | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54219840, COSV54238484; called by muse, mutect2, varscan2
- DNAH7 | c.10031G>A p.R3344H | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs769079675; called by muse, mutect2, varscan2
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 33/269 reads (12%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- DNALI1 | c.674T>C p.L225P (on ENST00000296218; = p.L203P on NM_003462.5) | Missense Mutation (SNP) | VAF 53/380 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192918992; called by muse, mutect2, varscan2
- DNM3 | c.2410C>T p.P804S (on ENST00000355305 / NM_001350206.2; = p.P798S on NM_015569.5) | Missense Mutation (SNP) | VAF 45/661 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.039); catalogued as rs774513620; called by muse, mutect2
- DNMT3A | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 61/521 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99065557; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 33/235 reads (14%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOP1A | c.6671del p.F2224Sfs*6 | Frame Shift Del (DEL) | VAF 42/385 reads (11%) | catalogued as COSV52708706; called by mutect2, pindel, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 32/310 reads (10%) | catalogued as rs35482889; called by mutect2, varscan2
- DRD5 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 48/476 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1340988476, COSV58576599; called by muse, mutect2, varscan2
- DRD5 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 48/405 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.136); catalogued as rs200800209, COSV58579805; called by muse, mutect2, varscan2
- DRG2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769319746; called by muse, mutect2, varscan2
- DSG1 | c.2587G>A p.V863I | Missense Mutation (SNP) | VAF 56/484 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.376); catalogued as rs1315158720; called by muse, mutect2, varscan2
- DSP | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 77/436 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs762135558, COSV65792655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 24/176 reads (14%) | catalogued as rs750962255; called by mutect2, varscan2
- DUOXA2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567165362; called by muse, mutect2, varscan2
- DUSP8 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 78/656 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs762127578, COSV100524195; called by muse, mutect2, varscan2
- DYRK1B | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs146458379; called by muse, mutect2
- EBF2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 32/507 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1423484193; called by muse, mutect2
- ECE1 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs768531939; called by muse, mutect2, varscan2
- EGR1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 70/692 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53522307; called by muse, mutect2
- EHBP1 | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 47/402 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs774730190; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 32/208 reads (15%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF2AK4 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.797); catalogued as rs750136639, COSV55464890; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | catalogued as rs748937918; called by mutect2, varscan2
- ELAC2 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.28); catalogued as rs543132773; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 40/338 reads (12%) | catalogued as rs766700925; called by mutect2, varscan2
- EML1 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs776900171, COSV51753379; called by muse, mutect2, varscan2
- EML5 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs765131444, COSV100714995; called by muse, mutect2, varscan2
- EMSY | c.3698C>T p.A1233V | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs776753070; called by muse, mutect2, varscan2
- ENC1 | c.538A>G p.R180G | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs776921094; called by muse, mutect2, varscan2
- ENO1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1278972141; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 38/269 reads (14%) | catalogued as rs761717176; called by mutect2, varscan2
- EPHA10 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 76/564 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs377655424; called by muse, mutect2, varscan2
- EPHA3 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as rs530556931, COSV60715953; called by muse, mutect2, varscan2
- EPHB1 | c.2305C>A p.L769I | Missense Mutation (SNP) | VAF 55/470 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV67668495; called by muse, mutect2, varscan2
- EPHB3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1302758661; called by muse, mutect2, varscan2
- EPS15 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs772614784, COSV65544388; called by muse, mutect2, varscan2
- ERMAP | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 65/492 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.2); catalogued as rs370783701; called by muse, mutect2, varscan2
- ERN2 | c.1197_1199del p.F399del | In Frame Del (DEL) | VAF 41/271 reads (15%) | catalogued as rs1306126388; called by pindel, varscan2
- ESPL1 | c.3882G>A p.W1294* | Nonsense Mutation (SNP) | VAF 72/510 reads (14%) | catalogued as rs373537189; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 44/388 reads (11%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRRG | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 61/452 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as rs1558221786, COSV63184975; called by muse, mutect2, varscan2
- ESX1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 120/893 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.314); catalogued as rs782488534, COSV65424506; called by muse, mutect2, varscan2
- ETV5 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112337; called by muse, mutect2, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 42/387 reads (11%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EXOSC5 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs139413206; called by muse, mutect2
- F2RL3 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 80/544 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs747353327, COSV99935409; called by muse, varscan2
- FAAH2 | c.385A>T p.T129S | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.889); catalogued as rs773590685; called by muse, mutect2, varscan2
- FAF1 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs371330134; called by muse, mutect2, varscan2
- FAM149B1 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs756665429; called by muse, mutect2
- FAM184B | c.2698G>T p.G900* | Nonsense Mutation (SNP) | VAF 34/302 reads (11%) | catalogued as rs958930827; called by muse, mutect2, varscan2
- FAM200A | c.1094del p.N365Tfs*12 | Frame Shift Del (DEL) | VAF 36/378 reads (10%) | catalogued as rs1268664972; called by mutect2, pindel, varscan2
- FAM47C | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 82/798 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV100792799; called by muse, mutect2
- FAM47C | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 70/572 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.047); catalogued as rs1194791411, COSV63725131; called by muse, mutect2, varscan2
- FAM83F | c.1161del p.V388Wfs*9 | Frame Shift Del (DEL) | VAF 66/676 reads (10%) | catalogued as rs1569234985; called by mutect2, pindel
- FAM83H | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 106/824 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1049092287; called by mutect2, varscan2
- FAM98B | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 76/551 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as rs1286283396; called by muse, mutect2, varscan2
- FARP2 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs137999067; called by muse, mutect2, varscan2
- FASN | c.6430A>G p.N2144D | Missense Mutation (SNP) | VAF 57/477 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as rs1298547010; called by muse, mutect2, varscan2
- FAT1 | c.1882C>T p.R628* | Nonsense Mutation (SNP) | VAF 52/464 reads (11%) | catalogued as rs766787268, COSV71671712; called by muse, mutect2, varscan2
- FBRSL1 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 94/682 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.138); catalogued as rs1350915696; called by muse, mutect2, varscan2
- FBXO31 | c.999C>T p.G333= | Splice Region (SNP) | VAF 33/296 reads (11%) | catalogued as rs371015325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO6 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs1239339753; called by muse, mutect2, varscan2
- FBXW12 | c.972_975del p.T325Sfs*16 | Frame Shift Del (DEL) | VAF 39/254 reads (15%) | catalogued as rs774760016; called by mutect2, pindel, varscan2
- FERMT2 | c.168del p.D57Ifs*17 | Frame Shift Del (DEL) | VAF 24/217 reads (11%) | catalogued as rs1225761410; called by mutect2, pindel, varscan2
- FEZ1 | c.314T>G p.V105G | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54028147; called by muse, mutect2
- FGD2 | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 67/571 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs759208124; called by muse, mutect2, varscan2
- FGF3 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 20/519 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782507721, COSV61925455, COSV61925479; ClinVar: uncertain significance; called by muse, mutect2
- FIBCD1 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.03); catalogued as rs571770324; called by muse, mutect2, varscan2
- FKBP11 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs760780010; called by muse, mutect2, varscan2
- FLCN | c.1243T>C p.C415R | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1567809578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 79/596 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61040878; called by muse, mutect2, varscan2
- FLOT1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 66/607 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs753643195, COSV52543509; called by muse, mutect2, varscan2
- FMN2 | c.4867G>T p.D1623Y | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60442966; called by muse, mutect2, varscan2
- FOXB2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 65/456 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1264813256; called by muse, varscan2
- FRAS1 | c.11183C>T p.T3728M | Missense Mutation (SNP) | VAF 41/476 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421779376, COSV53603806; called by muse, mutect2
- FRG2B | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs1029213146; called by muse, mutect2, varscan2
- FRMD6 | c.1483G>T p.G495* (on ENST00000344768 / NM_001267046.2; = p.G487* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 38/252 reads (15%) | catalogued as COSV61091390; called by muse, mutect2, varscan2
- FRMD8 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs761939885; called by muse, mutect2, varscan2
- FRS2 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375588784; called by muse, mutect2, varscan2
- FSCN3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148605578; called by muse, mutect2, varscan2
- FZR1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 65/746 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as rs371550562; called by muse, mutect2
- GABRB1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 74/553 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs78133797, COSV54991113; called by muse, mutect2, varscan2
- GALNT1 | c.353_355del p.T118del | In Frame Del (DEL) | VAF 28/274 reads (10%) | catalogued as rs770569348; called by pindel, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 39/258 reads (15%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GANAB | c.2060G>A p.W687* | Nonsense Mutation (SNP) | VAF 43/377 reads (11%) | catalogued as COSV100648222; called by muse, mutect2, varscan2
- GATA4 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 56/928 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as CM1010265; called by muse, mutect2
- GATAD2A | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768273089, COSV53068416; called by muse, mutect2, varscan2
- GBP4 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.1); catalogued as rs368648285; called by muse, mutect2, varscan2
- GCN1 | c.4757C>T p.T1586M | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs1286791171, COSV56104796; called by muse, mutect2, varscan2
- GDF9 | c.562A>G p.R188G | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760940033; called by muse, mutect2, varscan2
- GFPT2 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.35); catalogued as rs774417416, COSV53806218; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 84/369 reads (23%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP6 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 72/601 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs200301890, COSV61035384; called by muse, mutect2, varscan2
- GIN1 | c.212del p.K71Rfs*4 | Frame Shift Del (DEL) | VAF 40/390 reads (10%) | catalogued as rs1554196343; called by mutect2, pindel
- GJA3 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 63/567 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as rs1376480742; called by muse, mutect2, varscan2
- GK2 | c.388dup p.I130Nfs*5 | Frame Shift Ins (INS) | VAF 44/335 reads (13%) | catalogued as rs771628988; called by mutect2, varscan2
- GLG1 | c.1830C>A p.L610= | Splice Region (SNP) | VAF 38/253 reads (15%) | catalogued as COSV52670176; called by muse, mutect2, varscan2
- GLI3 | c.1448A>G p.H483R | Missense Mutation (SNP) | VAF 50/479 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as rs1420612792; called by muse, mutect2, varscan2
- GNB1L | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 55/478 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.13); catalogued as rs574576970; called by muse, mutect2, varscan2
- GNPTG | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as rs367661016; called by muse, varscan2
- GOLGA3 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199808370, COSV52635526; called by muse, mutect2, varscan2
- GPC2 | c.1047del p.D350Tfs*24 | Frame Shift Del (DEL) | VAF 110/476 reads (23%) | catalogued as rs748011069, COSV52786506; called by mutect2, varscan2
- GPR179 | c.2698del p.L900Cfs*70 (on ENST00000621958; = p.L899Cfs*70 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 99/801 reads (12%) | catalogued as rs1216773012; called by mutect2, pindel, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 50/364 reads (14%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR20 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 110/784 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775863809; called by muse, mutect2, varscan2
- GRAMD4 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765462301; called by muse, mutect2
- GREM1 | c.104del p.P35Rfs*49 | Frame Shift Del (DEL) | VAF 72/632 reads (11%) | catalogued as COSV55715863; called by mutect2, pindel, varscan2
- GRIA3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 69/500 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763033824, COSV99989783; called by muse, mutect2, varscan2
- GRIN2C | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 37/434 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1193967789, COSV99500836; called by muse, mutect2
- GRIP2 | c.1885G>A p.A629T (on ENST00000619221; = p.A532T on NM_001080423.4) | Missense Mutation (SNP) | VAF 65/406 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.263); catalogued as rs531605439, COSV56124206, COSV99816890; called by muse, mutect2, varscan2
- GRM5 | c.2893G>A p.A965T (on ENST00000305447 / NM_001143831.2; = p.A933T on NM_000842.4) | Missense Mutation (SNP) | VAF 87/642 reads (14%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV59604206; called by muse, mutect2, varscan2
- GRM7 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 68/564 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63175730; called by muse, mutect2, varscan2
- GSTA2 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 43/379 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs368356556; called by muse, mutect2, varscan2
- GTPBP6 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as rs1254596287; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 63/290 reads (22%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel, varscan2
- GYG1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900217907; called by muse, mutect2, varscan2
- GZMM | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 81/607 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV99198863; called by muse, mutect2, varscan2
- HAP1 | c.1634C>T p.A545V (on ENST00000310778 / NM_001367460.1; = p.A493V on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/572 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1555588429; called by muse, mutect2
- HCAR3 | c.316A>G p.M106V | Missense Mutation (SNP) | VAF 47/458 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV63678610; called by muse, mutect2, varscan2
- HCFC1 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 29/723 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60075658; called by muse, mutect2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 46/262 reads (18%) | catalogued as rs57105282; called by mutect2, varscan2
- HECTD3 | c.491A>G p.Q164R | Missense Mutation (SNP) | VAF 66/586 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as rs753154497, COSV55799019; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 40/301 reads (13%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HIVEP1 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 52/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs772385294, COSV65105297; called by muse, mutect2, varscan2
- HLF | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 79/553 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1374641219; called by muse, mutect2, varscan2
- HMCN1 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs886045671, COSV54914468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMGCL | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 35/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM078428, CM980991; called by muse, mutect2
- HOXC6 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 39/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54536835; called by muse, mutect2
- HTR1B | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 66/522 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64051593; called by muse, mutect2, varscan2
- HTR1E | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 71/518 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs758912640; called by muse, mutect2, varscan2
- ICA1L | c.111del p.E38Rfs*30 | Frame Shift Del (DEL) | VAF 42/331 reads (13%) | catalogued as rs1330717036; called by mutect2, pindel, varscan2
- IGF1R | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1441621301, COSV51271348; called by muse, mutect2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 48/342 reads (14%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFALS | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 90/656 reads (14%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs778060737; called by muse, varscan2
- IGFL2 | c.207dup p.C70Lfs*8 (on ENST00000377693 / NM_001135113.2; = p.C81Lfs*8 on NM_001002915.2) | Frame Shift Ins (INS) | VAF 77/472 reads (16%) | catalogued as rs1568434004; called by mutect2, pindel, varscan2
- IGHE | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs782372917; called by muse, mutect2, varscan2
- IGHV4-39 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 53/522 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1469664946; called by muse, mutect2, varscan2
- IGHV7-81 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs768280092; called by muse, varscan2
- IGKV5-2 | c.134C>G p.A45G | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs746002276; called by muse, mutect2
- IGLON5 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 55/457 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs770938120; called by muse, mutect2, varscan2
- IL13RA2 | c.806G>A p.C269Y | Missense Mutation (SNP) | VAF 33/420 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781997445; called by muse, mutect2
- IL16 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780472079, COSV57263126; called by muse, mutect2, varscan2
- IL1RL1 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 29/263 reads (11%) | catalogued as COSV52117152; called by muse, mutect2, varscan2
- IL27RA | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs772182491; called by muse, mutect2, varscan2
- INO80E | c.531del p.D178Tfs*8 | Frame Shift Del (DEL) | VAF 34/234 reads (15%) | catalogued as rs1339809802; called by pindel, varscan2
- INSM2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 89/637 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225976507, COSV99355053; called by muse, mutect2, varscan2
- INSRR | c.2757del p.L920Cfs*37 | Frame Shift Del (DEL) | VAF 47/444 reads (11%) | catalogued as rs772259106; called by mutect2, pindel, varscan2
- IQGAP2 | c.3935G>A p.R1312Q | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.153); catalogued as rs751420180; called by muse, mutect2, varscan2
- IQGAP3 | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 43/540 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs769667331, COSV63252251; called by muse, mutect2
- IQGAP3 | c.876C>T p.N292= | Splice Region (SNP) | VAF 49/377 reads (13%) | catalogued as rs143251488; called by muse, mutect2, varscan2
- IQSEC1 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 70/561 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs757663574; called by muse, varscan2
- IRF2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs376870150; called by muse, mutect2, varscan2
- IRF6 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 48/405 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770043363; called by muse, mutect2, varscan2
- IRX1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs1219682533; called by muse, varscan2
- ISG20 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775000659; called by muse, mutect2, varscan2
- ISLR | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs201880413, COSV51434728; called by muse, mutect2
- ITGAL | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.801); catalogued as rs1225279554, COSV63320137; called by muse, mutect2
- ITGB4 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs374855840; called by muse, mutect2, varscan2
- ITGB4 | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs571861704; called by muse, varscan2
- ITGB7 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1400411855; called by muse, mutect2, varscan2
- ITIH1 | c.138+3_138+6del p.X46_splice | Splice Site (DEL) | VAF 34/385 reads (9%) | catalogued as rs1169771791; called by mutect2, pindel
- ITIH6 | c.3599G>A p.R1200H | Missense Mutation (SNP) | VAF 71/602 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs775175752; called by muse, mutect2, varscan2
- ITPR3 | c.3689A>G p.Q1230R | Missense Mutation (SNP) | VAF 54/440 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.58); catalogued as COSV65414788; called by muse, mutect2, varscan2
- JADE2 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1436157662; called by muse, mutect2, varscan2
- JAG2 | c.2890G>A p.G964S | Missense Mutation (SNP) | VAF 90/663 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs753936530; called by muse, mutect2, varscan2
- JAM3 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 47/466 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as rs1219633820; called by muse, mutect2, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 30/208 reads (14%) | catalogued as rs1226801045; called by mutect2, varscan2
- KALRN | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 75/475 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781546248, COSV53783619; called by muse, mutect2, varscan2
- KARS1 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 15/314 reads (5%) | catalogued as rs1378809772; called by muse, mutect2
- KCNA3 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV63900847; called by muse, mutect2, varscan2
- KCNA6 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 63/535 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1239473214, COSV54974483; called by muse, mutect2, varscan2
- KCND1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 81/615 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs1557058524; called by muse, mutect2, varscan2
- KCNK15 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 87/601 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs372438657; called by muse, mutect2, varscan2
- KCNS1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 105/600 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1437506774; called by muse, mutect2, varscan2
- KCTD16 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV72579716; called by muse, varscan2
- KCTD21 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs967439472, COSV60741535; called by muse, mutect2, varscan2
- KHNYN | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 52/469 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52160088; called by muse, mutect2, varscan2
- KIAA0100 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370041492; called by muse, mutect2, varscan2
- KIAA1614 | c.1665del p.V556Sfs*21 | Frame Shift Del (DEL) | VAF 65/560 reads (12%) | catalogued as rs768029757; called by mutect2, pindel, varscan2
- KIAA1755 | c.3053G>T p.G1018V | Missense Mutation (SNP) | VAF 22/579 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs1206867549; called by muse, mutect2
- KIAA1755 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 79/577 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367812234, COSV54079454; called by muse, mutect2, varscan2
- KIAA2012 | c.1543del p.S515Vfs*25 | Frame Shift Del (DEL) | VAF 50/362 reads (14%) | catalogued as COSV99863055; called by mutect2, varscan2
- KIF13A | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs768904476; called by muse, mutect2, varscan2
- KIF15 | c.3373A>G p.M1125V | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs764553778; called by muse, mutect2
- KIF18B | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 63/429 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs755005838; called by muse, mutect2, varscan2
- KIF19 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 68/494 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs1277165700, COSV100739087; called by muse, mutect2, varscan2
- KIF20A | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs373433800; called by muse, mutect2, varscan2
- KIF27 | c.4076G>A p.C1359Y | Missense Mutation (SNP) | VAF 23/476 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1420401209; called by muse, mutect2
- KIF27 | c.3652C>T p.R1218W | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376993923, COSV52831217; called by muse, mutect2
- KIR2DL3 | c.718A>G p.N240D | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.097); catalogued as COSV60901004; called by muse, mutect2
- KLC2 | c.1700del p.G567Afs*11 | Frame Shift Del (DEL) | VAF 53/427 reads (12%) | catalogued as rs772643711; called by mutect2, pindel, varscan2
- KLF1 | c.588del p.Y197Tfs*40 | Frame Shift Del (DEL) | VAF 96/721 reads (13%) | catalogued as rs1360757265; called by mutect2, pindel, varscan2
- KLF17 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs766222742, COSV64856058; called by muse, mutect2, varscan2
- KLF7 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 62/530 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100519191; called by muse, mutect2, varscan2
- KLHL1 | c.104dup p.G36Rfs*12 | Frame Shift Ins (INS) | VAF 77/844 reads (9%) | catalogued as rs749011008; called by mutect2, pindel
- KLK11 | c.340G>T p.G114C (on ENST00000594768 / NM_144947.3; = p.G82C on NM_006853.3) | Missense Mutation (SNP) | VAF 25/583 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1384241014; called by muse, mutect2
- KMT2A | c.6191G>A p.R2064H | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782768278, COSV63281912; called by muse, mutect2, varscan2
- KRT26 | c.94A>G p.N32D | Missense Mutation (SNP) | VAF 48/446 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as rs762962352; called by muse, mutect2, varscan2
- KRT28 | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 57/489 reads (12%) | catalogued as rs200021509, COSV60684513; called by muse, mutect2, varscan2
- L3MBTL4 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs761891239, COSV53114527; called by muse, mutect2
- LAMB3 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 42/489 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.671); catalogued as rs113063967, COSV61916743; called by muse, mutect2
- LCE2A | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 85/597 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.019); catalogued as COSV100909142; called by muse, mutect2, varscan2
- LCMT2 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 51/486 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs561380150, COSV59790923; called by muse, mutect2, varscan2
- LGALS4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs574462249, COSV57042648; called by muse, mutect2, varscan2
- LIAS | c.371C>T p.A124V (on ENST00000261434 / NM_001363700.2; = p.A227V on NM_006859.4) | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as COSV99787667; called by muse, mutect2, varscan2
- LINC00514 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated, low confidence (0.28); catalogued as rs1036663542; called by muse, mutect2
- LLGL1 | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 36/735 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs973507004; called by muse, mutect2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 110/438 reads (25%) | catalogued as rs748712732; called by mutect2, varscan2
- LONP2 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 35/308 reads (11%) | catalogued as rs138063058; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 87/536 reads (16%) | catalogued as rs746133895; called by mutect2, varscan2
- LPAR1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62688291; called by muse, mutect2, varscan2
- LPO | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 64/499 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554132860, COSV51858115; called by muse, mutect2, varscan2
- LRFN1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 70/531 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437871632; called by muse, mutect2, varscan2
- LRFN4 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 82/550 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs748403576; called by muse, varscan2
- LRIT1 | c.52del p.Q18Rfs*26 | Frame Shift Del (DEL) | VAF 36/348 reads (10%) | catalogued as rs759958964; called by mutect2, pindel, varscan2
- LRP1 | c.10921G>A p.G3641S | Missense Mutation (SNP) | VAF 60/524 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs906119655; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 56/464 reads (12%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP2 | c.8254C>T p.R2752* | Nonsense Mutation (SNP) | VAF 31/386 reads (8%) | catalogued as COSV55542953; called by muse, mutect2
- LRP5 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 58/482 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908674, CM043028, CM152547; called by muse, mutect2, varscan2
- LRRC2 | c.95del p.V32Gfs*12 | Frame Shift Del (DEL) | VAF 38/386 reads (10%) | catalogued as COSV56126253, COSV56129105; called by mutect2, pindel, varscan2
- LRRC4B | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 53/542 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs867723776; called by muse, mutect2, varscan2
- LRRC66 | c.1087C>T p.Q363* | Nonsense Mutation (SNP) | VAF 73/476 reads (15%) | catalogued as COSV58636241; called by muse, mutect2, varscan2
- LRRC8A | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 76/528 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs565795685; called by muse, mutect2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 34/304 reads (11%) | catalogued as rs749244073; called by mutect2, varscan2
- LRRK1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 47/388 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs201889926; called by muse, mutect2, varscan2
- LSM1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 46/381 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1209698358, COSV60950137; called by muse, mutect2, varscan2
- MAD1L1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 29/368 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs749337220, COSV56226214; called by muse, mutect2
- MAGEB3 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 77/538 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100854841; called by muse, mutect2, varscan2
- MAGEC1 | c.3283G>T p.V1095F | Missense Mutation (SNP) | VAF 59/512 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs147835720, COSV53573381; called by muse, mutect2, varscan2
- MAGIX | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 92/598 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs1557097130; called by muse, mutect2, varscan2
- MALSU1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1211534967, COSV51685409; called by muse, mutect2, varscan2
- MAML3 | c.3128C>T p.A1043V | Missense Mutation (SNP) | VAF 77/614 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs763013687; called by muse, mutect2, varscan2
- MAN2B1 | c.2992C>T p.R998C | Missense Mutation (SNP) | VAF 51/461 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758755293, COSV99666948; called by muse, mutect2, varscan2
- MAP3K21 | c.570C>A p.C190* | Nonsense Mutation (SNP) | VAF 65/506 reads (13%) | catalogued as rs1442111909, COSV100786252; called by muse, mutect2, varscan2
- MAP3K4 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.08); catalogued as rs371051658, COSV62331728; called by muse, mutect2, varscan2
- MAP3K4 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs747018394, COSV62337164, COSV62339611; called by muse, mutect2, varscan2
- MAP3K6 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146979757; called by muse, mutect2, varscan2
- MAP4K4 | c.771del p.K257Nfs*10 | Frame Shift Del (DEL) | VAF 36/235 reads (15%) | catalogued as rs774203808; called by mutect2, pindel, varscan2
- MAP4K5 | c.793del p.R265Dfs*8 | Frame Shift Del (DEL) | VAF 38/270 reads (14%) | catalogued as rs746424357; called by mutect2, varscan2
- MAST1 | c.4322C>T p.A1441V | Missense Mutation (SNP) | VAF 73/585 reads (12%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs866290486; called by muse, mutect2, varscan2
- MBP | c.448G>A p.A150T (on ENST00000355994 / NM_001025101.2; = p.A17T on NM_002385.3) | Missense Mutation (SNP) | VAF 65/523 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs865949931; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 60/207 reads (29%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MECR | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 47/345 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.754); catalogued as rs200920712; called by muse, mutect2, varscan2
- MED1 | c.4609C>T p.P1537S | Missense Mutation (SNP) | VAF 59/501 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as rs755077180; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 80/851 reads (9%) | catalogued as rs745558596; called by mutect2, pindel
- MEGF8 | c.2344C>T p.R782W (on ENST00000251268 / NM_001271938.2; = p.R715W on NM_001410.3) | Missense Mutation (SNP) | VAF 76/571 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs1281253733, COSV52092313; called by muse, mutect2, varscan2
- MEI1 | c.1826T>C p.L609P | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV55901402; called by muse, mutect2
- MEIS2 | c.938C>T p.A313V (on ENST00000561208 / NM_170675.5; = p.A300V on NM_002399.3) | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1275580589, COSV54933650, COSV99576255; called by muse, varscan2
- MEIS3 | c.1060G>A p.V354M (on ENST00000558555 / NM_001346148.1; = p.V400M on NM_020160.3) | Missense Mutation (SNP) | VAF 57/463 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1329274302; called by muse, mutect2, varscan2
- MEOX2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 66/482 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1195725546; called by muse, varscan2
- MFAP1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs748393644, COSV51039002; called by muse, mutect2, varscan2
- MFSD10 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 52/610 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1426742371, COSV53275365; called by muse, mutect2
- MGAM | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV72075101; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 64/474 reads (14%) | catalogued as COSV54098507; called by mutect2, varscan2
- MINDY4B | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as rs908738248; called by muse, mutect2, varscan2
- MIS18A | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 60/542 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.067); catalogued as rs1345916109; called by muse, mutect2, varscan2
- MITF | c.1090G>A p.A364T (on ENST00000448226 / NM_006722.3; = p.A264T on NM_000248.4) | Missense Mutation (SNP) | VAF 59/482 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs780721280; called by muse, mutect2, varscan2
- MLH1 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 98/370 reads (26%) | catalogued as CD055711; called by muse, mutect2, varscan2
- MLXIPL | c.963del p.S322Afs*26 | Frame Shift Del (DEL) | VAF 75/657 reads (11%) | catalogued as rs782761791; called by mutect2, pindel, varscan2
- MRNIP | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 46/491 reads (9%) | catalogued as rs142061446; called by muse, mutect2
- MRPL45 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 37/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs769411482; called by muse, mutect2, varscan2
- MRTFA | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 90/750 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as rs373666097, COSV62933025, COSV62935045; called by muse, mutect2, varscan2
- MSX2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 52/489 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766037353; called by muse, mutect2, varscan2
- MTR | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs372611712; called by muse, mutect2, varscan2
- MUC12 | c.1936C>T p.P646S (on ENST00000379442; = p.P503S on NM_001164462.1) | Missense Mutation (SNP) | VAF 74/1852 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.65); catalogued as rs1445107139; called by muse, mutect2
- MUC17 | c.1549T>C p.S517P | Missense Mutation (SNP) | VAF 58/478 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751516957, COSV60294672; called by muse, mutect2, varscan2
- MUC3A | c.7795G>A p.V2599I | Missense Mutation (SNP) | VAF 55/519 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); catalogued as COSV60213340; called by muse, mutect2, varscan2
- MUC4 | c.5804C>T p.T1935M | Missense Mutation (SNP) | VAF 125/658 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as rs751605460; called by muse, mutect2, varscan2
- MUC6 | c.6752C>T p.T2251M | Missense Mutation (SNP) | VAF 97/823 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs199716176, COSV70150831; called by muse, mutect2, varscan2
- MUC6 | c.3265G>A p.A1089T | Missense Mutation (SNP) | VAF 78/580 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.057); catalogued as rs375978389, COSV101424663, COSV70142424; called by muse, mutect2, varscan2
- MXRA5 | c.7742G>A p.G2581D | Missense Mutation (SNP) | VAF 71/618 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs749861306; called by muse, mutect2, varscan2
- MXRA5 | c.2560G>A p.V854I | Missense Mutation (SNP) | VAF 65/588 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs41304705, COSV99477163; called by muse, mutect2, varscan2
- MYH11 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 58/584 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as rs371750065; called by muse, mutect2, varscan2
- MYH9 | c.3677G>A p.R1226Q | Missense Mutation (SNP) | VAF 48/600 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.108); catalogued as rs200697030, COSV53385328; ClinVar: uncertain significance; called by muse, mutect2
- MYO1A | c.3034G>A p.V1012M | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs535043825; called by muse, mutect2, varscan2
- MYO5A | c.4318del p.I1440Lfs*4 | Frame Shift Del (DEL) | VAF 30/271 reads (11%) | catalogued as rs1567030410; called by mutect2, pindel, varscan2
- MYO7A | c.4388G>A p.R1463H | Missense Mutation (SNP) | VAF 42/383 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs558085909, COSV68683208, COSV68685045; called by muse, varscan2
- MYOM2 | c.2651T>C p.V884A | Missense Mutation (SNP) | VAF 50/462 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV50741366; called by muse, mutect2, varscan2
- MYRF | c.1826G>A p.R609H (on ENST00000278836 / NM_001127392.3; = p.R600H on NM_013279.4) | Missense Mutation (SNP) | VAF 70/481 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1404580124; called by muse, mutect2, varscan2
- N4BP2 | c.5221C>T p.R1741C | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747259299; called by muse, mutect2, varscan2
- NAA10 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 26/475 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV64169366; called by muse, mutect2
- NAT10 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759711543; called by muse, mutect2, varscan2
- NEB | c.18620C>T p.T6207M | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs367921141, CM138112; called by muse, mutect2, varscan2
- NELFA | c.1426G>A p.G476S (on ENST00000542778; = p.G465S on NM_005663.5) | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141590096; called by muse, mutect2, varscan2
- NELFB | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767955431; called by muse, mutect2, varscan2
- NEURL4 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 53/325 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs369946100; called by muse, mutect2, varscan2
- NEXMIF | c.2455T>G p.L819V | Missense Mutation (SNP) | VAF 78/513 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50054319; called by muse, mutect2, varscan2
- NF1 | c.3125T>C p.V1042A | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV62224083; called by muse, mutect2, varscan2
- NFATC2 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 64/519 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs749298884, COSV101044752; called by muse, mutect2, varscan2
- NFKBIB | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs201937854; called by muse, mutect2
- NICN1 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs770325517, COSV56469961; called by muse, varscan2
- NIFK | c.859del p.R287Dfs*23 | Frame Shift Del (DEL) | VAF 34/313 reads (11%) | catalogued as COSV53535587; called by mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 36/280 reads (13%) | catalogued as rs145147241; called by mutect2, varscan2
- NKD2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 45/629 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs769392378; called by muse, mutect2
- NKX2-1 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 88/616 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760880632, CM142000, COSV61389649; called by muse, mutect2, varscan2
- NKX3-1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 72/476 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751677679; called by muse, varscan2
- NKX6-3 | c.646G>T p.G216C (on ENST00000518699 / NM_001364841.2; = p.G86C on NM_152568.3) | Missense Mutation (SNP) | VAF 81/759 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as COSV72895185; called by muse, mutect2, varscan2
- NLRC5 | c.2270A>G p.Q757R | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs202002811; called by muse, mutect2, varscan2
- NOL7 | c.714del p.K238Nfs*16 | Frame Shift Del (DEL) | VAF 24/198 reads (12%) | catalogued as rs544905440; called by mutect2, varscan2
- NOLC1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 45/486 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs192399476, COSV64180642; called by muse, mutect2
- NOXRED1 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 51/505 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs370161974, COSV100033102; called by muse, mutect2
- NPBWR2 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 77/562 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs143859764; called by muse, mutect2, varscan2
- NPHP4 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs1196644142, COSV65393234, COSV65396625; called by muse, mutect2, varscan2
- NRCAM | c.540G>T p.W180C (on ENST00000379028 / NM_001371124.1; = p.W174C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61036704; called by muse, mutect2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 76/316 reads (24%) | catalogued as rs776154715; called by mutect2, varscan2
- NRXN1 | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 56/532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58476192; called by muse, mutect2, varscan2
- NSRP1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs572953048, COSV55936160; called by muse, mutect2
- NT5M | c.622del p.R208Afs*34 | Frame Shift Del (DEL) | VAF 69/581 reads (12%) | catalogued as rs754390000; called by mutect2, pindel, varscan2
- NTN3 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 55/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364614453; called by muse, mutect2, varscan2
- NTPCR | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV64052656; called by muse, varscan2
- NTSR1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs535774214; called by muse, mutect2, varscan2
- NXF1 | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53677059; called by muse, mutect2, varscan2
- OASL | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 27/486 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs866108869, COSV57479180; called by muse, mutect2
- OBSL1 | c.458del p.G153Afs*105 | Frame Shift Del (DEL) | VAF 72/611 reads (12%) | catalogued as CX132462; called by mutect2, varscan2
- OCA2 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 34/403 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV100668859; called by muse, mutect2
- OPN1SW | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 54/510 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs62479596, COSV99975512; called by muse, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 48/488 reads (10%) | catalogued as rs753966040; called by mutect2, pindel
- OR10A6 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 65/565 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs149192400, COSV59165745; called by muse, mutect2, varscan2
- OR10G4 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV57977159; called by muse, mutect2
- OR10G6 | c.427C>A p.R143S | Missense Mutation (SNP) | VAF 66/476 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs760735886; called by muse, mutect2, varscan2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 46/517 reads (9%) | catalogued as rs752054889; called by mutect2, pindel
- OR4C16 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 68/521 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369412835; called by muse, mutect2, varscan2
- OR4D2 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 30/351 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV73459703; called by muse, mutect2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 20/174 reads (11%) | catalogued as rs1254479213; called by mutect2, pindel, varscan2
- OR56B1 | c.318C>A p.C106* | Nonsense Mutation (SNP) | VAF 48/298 reads (16%) | catalogued as rs774055727; called by muse, mutect2, varscan2
- OR6N1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 57/454 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99080319; called by muse, mutect2, varscan2
- OR7D2 | c.321del p.P108Lfs*8 | Frame Shift Del (DEL) | VAF 32/256 reads (13%) | catalogued as COSV100713019, COSV60139953; called by mutect2, pindel, varscan2
- OR8B4 | c.22T>G p.S8A | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.039); catalogued as rs1471603732; called by muse, mutect2
- OSBPL5 | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs777638746; called by muse, mutect2, varscan2
- OXTR | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 62/689 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs771532640, COSV57478750; called by muse, mutect2
- P2RX6 | c.186del p.G63Afs*39 | Frame Shift Del (DEL) | VAF 45/375 reads (12%) | catalogued as rs759868874, COSV99488575; called by mutect2, pindel, varscan2
- P2RX7 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 53/441 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.16); catalogued as COSV55854328; called by muse, mutect2, varscan2
- PAMR1 | c.1312C>T p.R438W (on ENST00000619888 / NM_001001991.3; = p.R455W on NM_015430.4) | Missense Mutation (SNP) | VAF 35/389 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763793747, COSV53510809; called by muse, mutect2
- PARD3 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs971596848, COSV60757444; called by muse, mutect2, varscan2
- PARP14 | c.4244del p.K1415Rfs*35 | Frame Shift Del (DEL) | VAF 34/326 reads (10%) | catalogued as rs1205949740; called by mutect2, pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 43/464 reads (9%) | catalogued as CM011452; called by mutect2, pindel
- PCBP2 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV63729338; called by muse, mutect2, varscan2
- PCCB | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.302); catalogued as COSV52448722; called by muse, mutect2, varscan2
- PCDH18 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61267069; called by muse, mutect2, varscan2
- PCDH19 | c.1742C>G p.S581C | Missense Mutation (SNP) | VAF 88/700 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV55273376; called by muse, mutect2, varscan2
- PCDH8 | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 66/571 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV100131261; called by muse, mutect2, varscan2
- PCDH8 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 61/573 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58810834; called by muse, varscan2
- PCDHA3 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 91/663 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs782148660, COSV65365989; called by muse, mutect2, varscan2
- PCDHGA9 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 67/511 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV99536689; called by muse, mutect2, varscan2
- PCDHGC4 | c.1885C>T p.R629W | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs775720601, COSV52767684; called by muse, mutect2, varscan2
- PCNX1 | c.5209G>A p.D1737N | Missense Mutation (SNP) | VAF 60/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53101403; called by muse, mutect2, varscan2
- PCSK9 | c.1975C>T p.R659W | Missense Mutation (SNP) | VAF 70/545 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs147182054; called by muse, varscan2
- PCYT2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs775332157; called by muse, mutect2, varscan2
- PDE1C | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 62/598 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101275345; called by muse, mutect2
- PDLIM7 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 36/357 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769613645, COSV63080288; called by muse, mutect2
- PDPK1 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.076); catalogued as rs965288790; called by muse, varscan2
- PDS5A | c.1495G>A p.V499I | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); catalogued as rs373353572, COSV57830342; called by muse, varscan2
- PDZRN4 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 95/687 reads (14%) | SIFT deleterious, low confidence (0.01); catalogued as rs1262384973; called by muse, mutect2, varscan2
- PHACTR3 | c.695del p.P232Hfs*30 | Frame Shift Del (DEL) | VAF 51/501 reads (10%) | catalogued as COSV63028198; called by mutect2, pindel, varscan2
- PHF20L1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 54/497 reads (11%) | catalogued as rs1429117928, COSV55192271; called by muse, mutect2, varscan2
- PHF23 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50039294; called by muse, mutect2
- PHF24 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 76/542 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751258396, COSV54274856; called by muse, mutect2, varscan2
- PHF7 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754969031, COSV59980429; called by muse, mutect2, varscan2
- PHGR1 | c.175del p.H59Tfs*49 | Frame Shift Del (DEL) | VAF 42/300 reads (14%) | catalogued as rs748850271; called by mutect2, varscan2
- PHLDA2 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 82/678 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1205092034; called by muse, mutect2, varscan2
- PHLPP1 | c.4964C>T p.P1655L | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867819447; called by muse, mutect2, varscan2
- PHTF1 | c.2075del p.K692Sfs*10 | Frame Shift Del (DEL) | VAF 29/251 reads (12%) | catalogued as rs752176716, COSV63368077; called by mutect2, pindel, varscan2
- PI15 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 62/447 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs558262570, COSV52640192; called by muse, mutect2, varscan2
- PI4KA | c.4334G>A p.R1445Q | Missense Mutation (SNP) | VAF 50/530 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.428); catalogued as rs934167301; called by muse, mutect2
- PIAS3 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57906586; called by muse, mutect2
- PIEZO1 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 68/609 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as rs547415243, COSV56337957; called by muse, mutect2, varscan2
- PIGC | c.247del p.H83Ifs*4 | Frame Shift Del (DEL) | VAF 61/374 reads (16%) | catalogued as rs1176830810; called by mutect2, pindel, varscan2
- PIK3C2G | c.3065G>A p.R1022H (on ENST00000676171; = p.R981H on NM_004570.5) | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.899); catalogued as rs762092026, COSV56821999; called by muse, mutect2
- PIK3R5 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 72/409 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759763454; called by muse, mutect2, varscan2
- PINX1 | c.950C>T p.T317M | Missense Mutation (SNP) | VAF 55/477 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs779941568, COSV59111109; called by muse, mutect2, varscan2
- PIP5K1C | c.1979dup p.A661Gfs*81 | Frame Shift Ins (INS) | VAF 64/404 reads (16%) | catalogued as rs748532409; called by mutect2, varscan2
- PIP5K1C | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 78/523 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs773061807; called by muse, mutect2, varscan2
- PIP5KL1 | c.680G>T p.R227L (on ENST00000388747 / NM_001135219.2; = p.R24L on NM_173492.1) | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199678461, COSV55944287; called by muse, mutect2, varscan2
- PITPNB | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs150364097; called by muse, mutect2
- PITPNM1 | c.884dup p.G296Rfs*37 | Frame Shift Ins (INS) | VAF 72/592 reads (12%) | catalogued as rs771198469; called by mutect2, varscan2
- PITRM1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs199659476, COSV56534814; called by muse, mutect2, varscan2
- PIWIL2 | c.2393del p.K798Sfs*5 | Frame Shift Del (DEL) | VAF 34/324 reads (10%) | catalogued as COSV63249731; called by mutect2, pindel, varscan2
- PKHD1L1 | c.6563dup p.S2190Ifs*39 | Frame Shift Ins (INS) | VAF 40/362 reads (11%) | catalogued as rs772426616; called by mutect2, varscan2
- PLA2G7 | c.948dup p.I317Yfs*4 | Frame Shift Ins (INS) | VAF 38/317 reads (12%) | catalogued as rs1363340574; called by mutect2, pindel, varscan2
- PLA2R1 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 42/465 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99323057; called by muse, mutect2
- PLAAT3 | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs753482856; called by muse, mutect2, varscan2
- PLBD2 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1185692906; called by muse, mutect2, varscan2
- PLEC | c.11726G>A p.R3909H (on ENST00000322810 / NM_201380.4; = p.R3799H on NM_000445.5) | Missense Mutation (SNP) | VAF 88/724 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs373965625; called by muse, mutect2, varscan2
- PLEC | c.9865G>A p.V3289M (on ENST00000322810 / NM_201380.4; = p.V3179M on NM_000445.5) | Missense Mutation (SNP) | VAF 81/650 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs781854050, COSV100520044; called by muse, mutect2, varscan2
- PLEC | c.6574G>A p.A2192T (on ENST00000322810 / NM_201380.4; = p.A2082T on NM_000445.5) | Missense Mutation (SNP) | VAF 88/656 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.019); catalogued as rs942658065; called by muse, mutect2, varscan2
- PLEKHN1 | c.1174C>T p.R392* (on ENST00000379409; = p.R340* on NM_032129.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/404 reads (11%) | catalogued as rs774553043; called by muse, mutect2, varscan2
- PLPPR3 | c.1460G>A p.R487H (on ENST00000520876 / NM_001270366.2; = p.R515H on NM_024888.2) | Missense Mutation (SNP) | VAF 90/675 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100609353; called by muse, mutect2, varscan2
- PLPPR5 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as COSV54175378; called by muse, varscan2
- PLXNA1 | c.2704G>A p.V902M | Missense Mutation (SNP) | VAF 72/529 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs145637703; called by muse, mutect2, varscan2
- PLXNA1 | c.5243G>A p.R1748H | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778054825; called by muse, mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 78/588 reads (13%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PNKP | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 61/444 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as rs746254179; called by muse, mutect2, varscan2
- PODNL1 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 85/670 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as rs963781438; called by muse, mutect2, varscan2
- PODXL2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 77/524 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs764073288, COSV61064451; called by muse, mutect2, varscan2
- POLE | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 51/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767503360, COSV57676074; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- POLN | c.625del p.S209Afs*3 | Frame Shift Del (DEL) | VAF 42/313 reads (13%) | catalogued as rs34428571; called by mutect2, pindel, varscan2
- POLR1A | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104379859; called by muse, mutect2, varscan2
- POLR1E | c.1010G>A p.R337Q (on ENST00000377792 / NM_001282766.1; = p.R275Q on NM_022490.4) | Missense Mutation (SNP) | VAF 48/490 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs750699084; called by muse, mutect2
- POLR3E | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.865); catalogued as rs775257915; called by muse, mutect2, varscan2
- POLRMT | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 69/657 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV73933366; called by muse, mutect2, varscan2
- POMGNT1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 61/409 reads (15%) | PolyPhen possibly damaging (0.814); catalogued as rs375420073; called by muse, mutect2, varscan2
- POU3F1 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 53/484 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.949); catalogued as rs536460366; called by muse, mutect2, varscan2
- PPFIA3 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 69/614 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1489695118, COSV61949337; called by muse, mutect2, varscan2
- PPM1H | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs557575879, COSV57372889; called by muse, mutect2, varscan2
- PPP1R13L | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 45/523 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62908252; called by muse, mutect2
- PPP2R2C | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 52/441 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs759923972, COSV59447755; called by muse, mutect2, varscan2
- PQBP1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781870298; called by muse, mutect2, varscan2
- PRDM8 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100324887; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 46/358 reads (13%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKAG1 | c.186del p.F62Lfs*4 | Frame Shift Del (DEL) | VAF 51/302 reads (17%) | catalogued as rs1565733883; called by mutect2, varscan2
- PRKCD | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 66/465 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV100387928; called by muse, mutect2, varscan2
- PRPF4 | c.970C>T p.R324C (on ENST00000374198 / NM_001322267.2; = p.R325C on NM_004697.5) | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144672283; called by muse, mutect2, varscan2
- PRPF40A | c.2644dup p.R882Kfs*15 | Frame Shift Ins (INS) | VAF 44/303 reads (15%) | catalogued as rs1464958512; called by mutect2, varscan2
- PRRT4 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 49/444 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as rs375091041, COSV71054258; called by muse, mutect2, varscan2
- PRUNE2 | c.4800G>T p.K1600N | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.386); catalogued as COSV65037629; called by muse, mutect2, varscan2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 28/273 reads (10%) | catalogued as rs761494960; called by mutect2, pindel, varscan2
- PSD2 | c.538del p.L180Sfs*56 | Frame Shift Del (DEL) | VAF 78/631 reads (12%) | catalogued as rs1361260068, COSV51214782; called by mutect2, pindel, varscan2
- PSD4 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141452297; called by muse, mutect2, varscan2
- PTF1A | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 74/751 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1325439993; called by muse, mutect2, varscan2
- PTPN9 | c.1780T>C p.*594Qext*23 | Nonstop Mutation (SNP) | VAF 38/274 reads (14%) | catalogued as COSV60723194; called by muse, mutect2, varscan2
- PTPRD | c.2444A>C p.K815T | Missense Mutation (SNP) | VAF 47/351 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs1434814256; called by muse, mutect2, varscan2
- PTPRS | c.3253C>T p.L1085F | Missense Mutation (SNP) | VAF 49/437 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1379503828; called by muse, mutect2, varscan2
- PTPRS | c.3072del p.V1025Sfs*18 | Frame Shift Del (DEL) | VAF 52/453 reads (11%) | catalogued as rs756013055, COSV53629833; called by mutect2, pindel, varscan2
- PWWP3A | c.280G>A p.V94M (on ENST00000627377; = p.V93M on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs527257850; called by muse, mutect2, varscan2
- PXDNL | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 142/581 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV62480161; called by muse, mutect2, varscan2
- QRFPR | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as rs539221428; called by muse, mutect2
- RAD21 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 19/519 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV52065286; called by muse, mutect2
- RAD9A | c.1002del p.K335Rfs*62 | Frame Shift Del (DEL) | VAF 36/339 reads (11%) | catalogued as rs756633055; called by mutect2, pindel, varscan2
- RAI1 | c.3103del p.Q1035Rfs*29 | Frame Shift Del (DEL) | VAF 69/662 reads (10%) | catalogued as rs774789734; called by mutect2, pindel, varscan2
- RAI1 | c.4615C>T p.R1539C | Missense Mutation (SNP) | VAF 87/551 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs747006500; called by muse, mutect2, varscan2
- RAI1 | c.5265del p.R1756Gfs*94 | Frame Shift Del (DEL) | VAF 109/622 reads (18%) | catalogued as rs867108845; called by mutect2, pindel, varscan2
- RALB | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 62/474 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs755448540; called by muse, mutect2, varscan2
- RALGAPA2 | c.2749G>A p.G917R | Missense Mutation (SNP) | VAF 51/395 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs566154629, COSV52507168, COSV52516256; called by muse, mutect2, varscan2
- RANBP2 | c.6269C>T p.T2090M | Missense Mutation (SNP) | VAF 50/596 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1175247304, COSV51707600; called by muse, mutect2
- RAP1GAP | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 50/568 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV51571492; called by muse, mutect2
- RARG | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 83/539 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1446141610; called by muse, mutect2, varscan2
- RASGRF2 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 59/398 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs988626160, COSV54138727; called by muse, mutect2, varscan2
- RASSF10 | c.911C>A p.A304E | Missense Mutation (SNP) | VAF 75/615 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as rs1218256054; called by muse, mutect2, varscan2
- RBM27 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV54588446; called by muse, mutect2, varscan2
- RBM41 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52564801; called by muse, mutect2, varscan2
- RBM44 | c.675T>G p.I225M (on ENST00000611254; = p.I859M on NM_001080504.2) | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1408168260; called by muse, mutect2, varscan2
- RBMXL3 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 84/693 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.428); catalogued as rs1487132568; called by muse, mutect2, varscan2
- RECK | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs748623772, COSV65034760, COSV65036409; called by muse, mutect2, varscan2
- RELA | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1478374154, COSV58013876; called by muse, mutect2, varscan2
- RELB | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs62117229; called by muse, mutect2, varscan2
- RERE | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 64/658 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs767001616; called by muse, mutect2
- REST | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 17/408 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as CM1513327, COSV100470822; called by muse, mutect2
- REST | c.3257T>C p.V1086A | Missense Mutation (SNP) | VAF 43/359 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV58362244; called by muse, mutect2, varscan2
- REXO1 | c.3431T>C p.L1144P | Missense Mutation (SNP) | VAF 46/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219358024; called by muse, mutect2, varscan2
- RGPD4 | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 30/281 reads (11%) | catalogued as rs556511922, COSV61745285; called by mutect2, varscan2
- RGS14 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1177082494; called by muse, mutect2
- RHPN2 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 60/448 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs753950362, COSV54279253; called by muse, mutect2, varscan2
- RIBC1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 65/513 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.825); catalogued as rs782705066; called by muse, mutect2, varscan2
- RLF | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1346414728, COSV65652196; called by muse, mutect2
- RNF123 | c.2788G>A p.V930M | Missense Mutation (SNP) | VAF 45/386 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751148620; called by muse, mutect2, varscan2
- RNF130 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1221302432, COSV56149497; called by muse, mutect2, varscan2
- RNF207 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 46/393 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs538875559; called by muse, mutect2, varscan2
- RNF213 | c.13039G>A p.E4347K | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs776162319, COSV60389718; called by muse, mutect2, varscan2
- ROBO3 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs770617692, COSV67299481; called by muse, mutect2, varscan2
- ROBO4 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.138); catalogued as COSV60622250; called by muse, varscan2
- ROR2 | c.1855C>A p.R619S | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65220025, COSV65220766; called by muse, mutect2
- RPE65 | c.886del p.R296Gfs*29 | Frame Shift Del (DEL) | VAF 44/345 reads (13%) | catalogued as rs746127684; called by mutect2, varscan2
- RPL36A-HNRNPH2 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 62/488 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1555988249; called by muse, mutect2, varscan2
- RPS6 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 41/271 reads (15%) | catalogued as rs780806374, COSV59547728; called by muse, mutect2, varscan2
- RPS6KL1 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774482304, COSV63581248; called by muse, mutect2, varscan2
- RPUSD1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 60/479 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416441008, COSV50099738, COSV50101333; called by muse, mutect2, varscan2
- RRN3 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs374353637; called by muse, mutect2
- RSF1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 57/466 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs748850046, COSV100407151; called by muse, mutect2, varscan2
- RSRC1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs759068571; called by muse, mutect2, varscan2
- RTTN | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs183531175; called by muse, mutect2
- RUNDC3B | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 57/579 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.368); catalogued as rs767918635; called by muse, mutect2, varscan2
- SAE1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs1362973401; called by muse, varscan2
- SAMD8 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 46/314 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419458107, COSV65509832; called by muse, mutect2, varscan2
- SAMHD1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1311797673, COSV53428109; called by muse, mutect2, varscan2
- SCAF4 | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 55/451 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs750354829, COSV54255534; called by muse, mutect2, varscan2
- SCAPER | c.3249G>T p.Q1083H | Missense Mutation (SNP) | VAF 64/459 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV100239200; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 32/212 reads (15%) | catalogued as rs765136101; called by mutect2, varscan2
- SCRIB | c.2743G>A p.V915I | Missense Mutation (SNP) | VAF 57/540 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.843); catalogued as rs782766244; called by muse, mutect2, varscan2
1,924 further variants in this file (1,236 protein-altering or splice-affecting, 594 silent, 94 other) are not listed here.
